CPTAC case C3N-03939 — Brain — Gliomas (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Gliomas; Primary site: Brain. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/2ce53fd9-c1a9-4a43-9c66-ee4364450cdc

Demographics
Sex at birth: female; Race: asian; Year of birth: 1969; Vital status: Dead; Days to death: 770 days (2.1 years); Year of death: 2020; Cause of death: Cancer Related; Country of birth: China.

Diagnoses (1)
1. Glioblastoma: ICD-O-3 morphology code: 9440/3; Tissue or organ of origin: Brain, NOS; Site of resection or biopsy: Temporal lobe; Age at diagnosis: 48.8 years (17,835 days); Year of diagnosis: 2018; Last known disease status: With tumor; Days to last known disease status: 770 days (2.1 years); Progression or recurrence: yes; Days to recurrence: 307 days; Days to last follow up: 1,051 days (2.9 years).
   Pathology details: Greatest tumor dimension: 4.5 cm.
   Chemotherapy — whether it was given is not recorded by GDC; Treatment outcome: Complete Response.
   Radiation Therapy, NOS — whether it was given is not recorded by GDC; Treatment outcome: Complete Response.

Follow-up (4 entries)
- Days to follow up: 358 days; Disease response: With Tumor; Karnofsky performance status: 60; ECOG performance status: 3.
- Days to follow up: 689 days (1.9 years); Disease response: With Tumor; Karnofsky performance status: 70; ECOG performance status: 2.
- Days to follow up: 689 days (1.9 years); Disease response: Progressive Disease; Progression or recurrence: Yes; Days to recurrence: 307 days; Karnofsky performance status: 70; ECOG performance status: 2.
- Days to follow up: 1,051 days (2.9 years); Disease response: With Tumor; Karnofsky performance status: 0; ECOG performance status: 5.

Other clinical attributes
- Weight: 51 kg; Height: 156 cm; BMI: 20.96.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker; Alcohol history: No; Alcohol intensity: Lifelong Non-Drinker.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample C3N-03939-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Brain; Biospecimen laterality: Left; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: -6 days; Initial weight: 130 mg; Time between excision and freezing: 12 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3N-03939-22: Section location: Temporal Lobe; Percent tumor nuclei: 80; Percent necrosis: 3.
- Sample C3N-03939-31: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC); Days to sample procurement: -6 days; Method of sample procurement: Blood Draw.
